Somatic mutation profile of cancer-model specimen HCM-SANG-0286-C20-85A (3D Organoid; aliquot HCM-SANG-0286-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0286-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0286-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 769c5610-6539-409d-9ba3-bc2fb4aa490c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0286-C20-10B (Blood Derived Normal), aliquot HCM-SANG-0286-C20-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4915f72e-9d71-4537-be51-cbab25640249

The open-access MAF lists 300 somatic variants for this specimen: 233 protein-altering or splice-affecting, 55 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 55, Frame Shift Del 15, Intron 8, Nonsense Mutation 8, In Frame Del 4, Frame Shift Ins 3, Nonstop Mutation 2, Translation Start Site 2, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 102/224 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 222/340 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 242/311 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TCTN2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as rs187433682, CM123333; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 228/229 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 167/528 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs759547568; called by muse, mutect2, varscan2
- ABCC5 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751998938, COSV99656497; called by muse, mutect2
- ACAD9 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 186/301 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs770234633; called by muse, mutect2, varscan2
- ACCS | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 143/452 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs370192805; called by muse, mutect2, varscan2
- ADD3 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 213/325 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.241); catalogued as COSV53326488; called by muse, mutect2, varscan2
- ANKRD12 | c.3359T>G p.I1120R | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100042124, COSV50849688; called by muse, mutect2, varscan2
- ANKRD18B | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs932101283; called by muse, mutect2, varscan2
- AP2A1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 124/245 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.813); catalogued as rs769598908, COSV58242828, COSV58243026; called by muse, mutect2, varscan2
- APC | c.3544A>T p.K1182* | Nonsense Mutation (SNP) | VAF 40/280 reads (14%) | catalogued as CD021192, COSV57341394; called by muse, mutect2, varscan2
- AQP4 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV67219042; called by muse, mutect2, varscan2
- ARHGEF11 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.263); catalogued as rs368365495, COSV59357082; called by muse, mutect2, varscan2
- B3GAT1 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 299/376 reads (80%) | catalogued as rs1035380375; called by muse, mutect2, varscan2
- CACNA1H | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 133/222 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1199006718; called by muse, mutect2, varscan2
- CACNA1S | c.4679G>A p.R1560Q | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372436488; called by muse, mutect2, varscan2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 207/317 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CATSPER1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 203/614 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372082637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK20 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs28364955; called by muse, mutect2
- CFAP47 | c.2505T>G p.S835R | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.786); catalogued as COSV52883371; called by muse, mutect2, varscan2
- CHD6 | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498626; called by muse, mutect2
- CNKSR3 | c.1494C>G p.D498E | Missense Mutation (SNP) | VAF 349/351 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101401283; called by muse, mutect2, varscan2
- EML1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 207/207 reads (100%) | catalogued as COSV99214946; called by muse, mutect2, varscan2
- FAT3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1001662868, COSV53111028; called by muse, mutect2
- FAT4 | c.7816G>A p.A2606T | Missense Mutation (SNP) | VAF 117/225 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747229172, COSV58683547; called by muse, mutect2, varscan2
- FHOD3 | c.3035A>G p.K1012R (on ENST00000359247 / NM_001281739.3; = p.K1029R on NM_025135.5) | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.87); catalogued as rs1459567596; called by muse, mutect2, varscan2
- FRAS1 | c.7084C>T p.R2362* | Nonsense Mutation (SNP) | VAF 141/273 reads (52%) | catalogued as rs777438557; called by muse, mutect2, varscan2
- H2AC15 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 120/496 reads (24%) | catalogued as rs746231334; called by pindel, varscan2
- HECTD3 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1390520764, COSV64670611; called by muse, mutect2, varscan2
- HIVEP1 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65099007; called by muse, mutect2
- HNRNPCL1 | c.311T>A p.M104K | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs778148450; called by muse, mutect2, varscan2
- IGSF10 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 249/329 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs372539492; called by muse, mutect2, varscan2
- JPH3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 528/534 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759496599; called by muse, mutect2, varscan2
- KANSL1L | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 261/363 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754026837; called by muse, mutect2, varscan2
- KCNH5 | c.2798A>C p.K933T | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100527468; called by muse, mutect2, varscan2
- KLK1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs768176494; called by muse, mutect2, varscan2
- LRP12 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 174/175 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs770729650, COSV52626697; called by muse, mutect2, varscan2
- MUC16 | c.11659A>T p.N3887Y | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs1227647715; called by muse, mutect2
- MUC7 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 148/302 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1316927617; called by muse, mutect2, varscan2
- MYO15A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 459/460 reads (100%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs934249137, COSV52761349; called by muse, mutect2, varscan2
- MYOF | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100826024; called by muse, mutect2, varscan2
- NDN | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as rs993170550, COSV100086154, COSV100086535; called by muse, mutect2
- NDUFS1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181556411, COSV51911186; called by muse, mutect2, varscan2
- NLRP14 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs755981014; called by muse, mutect2, varscan2
- NLRP8 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759131290, COSV52587344; called by muse, mutect2, varscan2
- OR2J1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 408/409 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.582); catalogued as rs777091944, COSV65850450; called by muse, mutect2
- OR6Q1 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV56933511; called by muse, mutect2, varscan2
- OTOF | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 198/307 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs200972155; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 318/489 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA9 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 64/621 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs140634296; called by muse, mutect2, varscan2
- PCDHB2 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52032822; called by muse, mutect2
- PEX5 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV56955562; called by muse, mutect2, varscan2
- PIEZO2 | c.5908G>A p.V1970I | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.98); PolyPhen benign (0.428); catalogued as rs780925886, COSV53287366; called by muse, varscan2
- PKD1L1 | c.6668G>A p.R2223H | Missense Mutation (SNP) | VAF 47/566 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs563223320, COSV56977907; called by muse, mutect2
- PLAGL2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 69/566 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as rs776363024; called by muse, mutect2, varscan2
- PLD2 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.93); catalogued as rs777822488; called by muse, mutect2, varscan2
- PRKAA2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs370738439, COSV64802734; called by muse, mutect2, varscan2
- PTCHD4 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 84/433 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV59786302; called by muse, mutect2, varscan2
- RBBP6 | c.53C>G p.T18S | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs938522432; called by muse, mutect2
- RBM12 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1250216283, COSV58290944; called by muse, mutect2, varscan2
- RINT1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57560961; called by muse, mutect2
- RIPK4 | c.1549C>T p.R517C (on ENST00000352483; = p.R469C on NM_020639.3) | Missense Mutation (SNP) | VAF 447/456 reads (98%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs771190743; called by muse, mutect2, varscan2
- SLC45A2 | c.454T>C p.F152L | Missense Mutation (SNP) | VAF 109/450 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as rs202120684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A17 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs767666097; called by muse, mutect2, varscan2
- SLITRK1 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 123/344 reads (36%) | catalogued as rs751727163; called by muse, mutect2, varscan2
- SPEM3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142001182; called by muse, mutect2, varscan2
- SPRR2G | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 225/585 reads (38%) | PolyPhen possibly damaging (0.619); catalogued as COSV64203496; called by muse, mutect2, varscan2
- SRC | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 122/595 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252138081, COSV62441668; called by muse, mutect2, varscan2
- SZT2 | c.7892G>A p.R2631H (on ENST00000634258 / NM_001365999.1; = p.R2574H on NM_015284.4) | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs769989601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANC1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 81/356 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs757915552, COSV55083923; called by muse, mutect2, varscan2
- TENM3 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 155/299 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1324480533, COSV69301962, COSV69311034; called by muse, mutect2, varscan2
- TFDP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 39/470 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64740014; called by muse, mutect2
- TLR4 | c.1951G>C p.V651L (on ENST00000355622 / NM_138554.5; = p.V611L on NM_003266.4) | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV100842935, COSV62924327; called by muse, mutect2, varscan2
- TMEM237 | c.961A>T p.I321L (on ENST00000409883 / NM_001044385.3; = p.I313L on NM_152388.4) | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53807523; called by muse, mutect2, varscan2
- TNXB | c.9553G>A p.A3185T (on ENST00000647633; = p.A2938T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as rs780721675, COSV64488384; called by muse, mutect2, varscan2
- TRIM71 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 189/362 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1455479185, COSV101070493; called by muse, mutect2, varscan2
- TTN | c.100141G>A p.E33381K (on ENST00000591111; = p.E25957K on NM_003319.4) | Missense Mutation (SNP) | VAF 104/394 reads (26%) | PolyPhen probably damaging (0.994); catalogued as rs727504977, COSV60089185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.58366A>G p.I19456V (on ENST00000591111; = p.I12032V on NM_003319.4) | Missense Mutation (SNP) | VAF 51/362 reads (14%) | PolyPhen benign (0.184); catalogued as COSV60223453; called by muse, mutect2, varscan2
- A2M | c.3682del p.L1228* | Frame Shift Del (DEL) | VAF 36/331 reads (11%) | called by mutect2, pindel, varscan2
- ABAT | c.1409A>G p.K470R | Missense Mutation (SNP) | VAF 81/497 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 109/417 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ACKR3 | c.1076del p.Q359Rfs*40 | Frame Shift Del (DEL) | VAF 28/196 reads (14%) | called by mutect2, pindel*, varscan2
- ALDH1L1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ALDH4A1 | c.1025A>C p.E342A | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 204/346 reads (59%) | called by mutect2, pindel, varscan2
- AQP4 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARID1A | c.482_490del p.V161_A163del | In Frame Del (DEL) | VAF 233/527 reads (44%) | called by mutect2, pindel, varscan2
- ATP6V1E1 | c.226A>C p.M76L | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBOX1 | c.1151A>C p.E384A | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BCL2L15 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- BLVRB | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BMP10 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 154/409 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFC | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- BRWD3 | c.2048T>G p.L683R | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C2orf76 | c.135T>G p.D45E | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CACNA1E | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CAMKV | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CCDC136 | c.3385C>A p.P1129T | Missense Mutation (SNP) | VAF 49/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC168 | c.6107A>G p.H2036R | Missense Mutation (SNP) | VAF 158/476 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC88B | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CD8B2 | c.471A>T p.L157F | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH6 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 256/383 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CIP2A | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 69/464 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COPG1 | c.1086_1091del p.K362_I364delinsN | In Frame Del (DEL) | VAF 38/424 reads (9%) | called by mutect2, pindel
- CSMD1 | c.8236G>C p.A2746P (on ENST00000520002; = p.A2745P on NM_033225.6) | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGKB | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMXL1 | c.4675_4678del p.A1559Ifs*22 | Frame Shift Del (DEL) | VAF 24/256 reads (9%) | called by mutect2, pindel
- DNAH17 | c.6113A>C p.D2038A | Missense Mutation (SNP) | VAF 15/453 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK7 | c.3689C>G p.S1230C (on ENST00000635253 / NM_001367561.1; = p.S1199C on NM_033407.3) | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- DPP10 | c.1018del p.A340Lfs*23 | Frame Shift Del (DEL) | VAF 28/266 reads (11%) | called by mutect2, pindel, varscan2
- FBXO38 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FBXW7 | c.937A>G p.I313V (on ENST00000281708 / NM_001349798.2; = p.I233V on NM_018315.5) | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCHSD1 | c.832A>C p.S278R | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FOXI3 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- FSD2 | c.2250G>C p.*750Yext*24 | Nonstop Mutation (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- GAB1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GADD45GIP1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GDF10 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 56/428 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, varscan2
- GDF10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 56/433 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- GPR101 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 103/445 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRP | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 75/250 reads (30%) | called by muse, mutect2, varscan2
- HDAC3 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIF1AN | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HPSE2 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- IGSF6 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 70/474 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IL1RL2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- IRS2 | c.181A>C p.T61P | Missense Mutation (SNP) | VAF 122/760 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.229); called by muse, varscan2
- ITPRID2 | c.720dup p.R241Sfs*4 | Frame Shift Ins (INS) | VAF 32/167 reads (19%) | called by mutect2, pindel, varscan2
- KCNC1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.194); called by muse, mutect2
- KCNG2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 196/418 reads (47%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KCNH5 | c.726del p.N243Tfs*3 | Frame Shift Del (DEL) | VAF 40/300 reads (13%) | called by mutect2, pindel, varscan2
- KLF13 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KMT2D | c.4016T>A p.L1339Q | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KNDC1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 273/795 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRP1B | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRC37A2 | c.2667T>G p.S889R | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRCC1 | c.1945G>A p.V649I | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRN1 | c.24_41del p.I8_V14delinsM | In Frame Del (DEL) | VAF 58/187 reads (31%) | called by mutect2, pindel, varscan2
- LRTM2 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 128/740 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.10418T>C p.V3473A | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MAGI2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 196/360 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MAP9 | c.1006T>A p.S336T | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2
- MTUS1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MUC12 | c.1756A>T p.S586C (on ENST00000379442; = p.S443C on NM_001164462.1) | Missense Mutation (SNP) | VAF 106/684 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- MYOF | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NAP1L4 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 285/429 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- NDN | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- NEURL1 | c.839C>G p.S280W | Missense Mutation (SNP) | VAF 60/659 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2
- NLRX1 | c.447_448del p.F150* | Frame Shift Del (DEL) | VAF 80/704 reads (11%) | called by pindel, varscan2
- NMBR | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2
- NMT2 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 350/548 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); called by muse, varscan2
- NMUR2 | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 288/471 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NTSR2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 81/650 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NUAK1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 274/419 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NXNL1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 231/472 reads (49%) | called by muse, mutect2, varscan2
- OAT | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- OR2AG2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR8B12 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); called by mutect2, varscan2
- P2RX6 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPN1L | c.95_122del p.A32Gfs*52 | Frame Shift Del (DEL) | VAF 102/475 reads (21%) | called by mutect2, pindel, varscan2
- PCDH11X | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PDXK | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF21A | c.1339_1340insAC p.S447Yfs*56 | Frame Shift Ins (INS) | VAF 91/531 reads (17%) | called by mutect2, varscan2
- PLPPR4 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PLXNB3 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 562/564 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.109); called by muse, varscan2
- PODXL2 | c.483A>T p.R161S | Missense Mutation (SNP) | VAF 138/449 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLD2 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 316/725 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREP | c.665G>A p.G222E (on ENST00000369110; = p.G288E on NM_002726.5) | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PREP | c.593G>T p.C198F (on ENST00000369110; = p.C264F on NM_002726.5) | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2
- PRKDC | c.7127A>G p.D2376G | Missense Mutation (SNP) | VAF 217/218 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRR9 | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRSS56 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 104/574 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PSPC1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 52/439 reads (12%) | called by muse, mutect2, varscan2
- PTCD3 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PYHIN1 | c.1479A>C p.*493Yext*29 | Nonstop Mutation (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2
- RAI14 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASA2 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 68/566 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASSF1 | c.11_18del p.E4Afs*3 | Frame Shift Del (DEL) | VAF 65/301 reads (22%) | called by mutect2, pindel, varscan2
- RBM43 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- RIMBP2 | c.572A>G p.E191G | Missense Mutation (SNP) | VAF 69/418 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF130 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 195/306 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF182 | c.664A>G p.S222G | Missense Mutation (SNP) | VAF 74/433 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RNF213 | c.2813_2819del p.V938Gfs*48 | Frame Shift Del (DEL) | VAF 36/241 reads (15%) | called by mutect2, pindel, varscan2
- SCG3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN8A | c.4325T>A p.I1442N | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- SEC24C | c.2951A>G p.E984G | Missense Mutation (SNP) | VAF 90/475 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETBP1 | c.1053C>G p.D351E | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SGCG | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC17A7 | c.1435C>G p.H479D | Missense Mutation (SNP) | VAF 157/328 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SLC35F4 | c.1482G>C p.E494D (on ENST00000339762 / NM_001352015.2; = p.E458D on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC38A10 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SLC49A3 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 233/488 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC4A8 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 235/350 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SLITRK5 | c.1550_1562del p.L517Pfs*8 | Frame Shift Del (DEL) | VAF 72/436 reads (17%) | called by mutect2, pindel, varscan2
- SORBS1 | c.2111G>A p.S704N (on ENST00000361941 / NM_001034954.2; = p.S410N on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SPATA31A3 | c.1647G>C p.R549S | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, varscan2
- SPDYA | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPEG | c.8816T>A p.V2939D | Missense Mutation (SNP) | VAF 101/452 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STOX2 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 81/518 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SYNE1 | c.7916G>T p.W2639L (on ENST00000367255 / NM_182961.4; = p.W2646L on NM_033071.3) | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TCF7L1 | c.345A>C p.K115N | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDRD1 | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- THAP10 | c.455A>T p.Q152L | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMEM178B | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 114/764 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM233 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNKS1BP1 | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 101/578 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- TRHDE | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 210/650 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, varscan2
- TRIM24 | c.2573C>A p.T858K (on ENST00000343526 / NM_015905.3; = p.T824K on NM_003852.4) | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM64B | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIP12 | c.2220A>T p.K740N | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TTI1 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 53/617 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TTLL7 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- TTN | c.66770A>G p.E22257G (on ENST00000591111; = p.E14833G on NM_003319.4) | Missense Mutation (SNP) | VAF 98/408 reads (24%) | PolyPhen possibly damaging (0.747); called by muse, varscan2
- UBLCP1 | c.528T>G p.D176E | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3204A>C p.E1068D | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ULK1 | c.1157_1157+3del | Frame Shift Del (DEL) | VAF 66/572 reads (12%) | called by mutect2, pindel, varscan2
- UNCX | c.475A>C p.K159Q | Missense Mutation (SNP) | VAF 72/525 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP34 | c.1106T>G p.L369R | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP48 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- VANGL2 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 17/567 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- XKR6 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 54/472 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- XRCC1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED2 | c.644del p.F215Sfs*13 | Frame Shift Del (DEL) | VAF 53/374 reads (14%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.551_552dup p.S185Afs*3 | Frame Shift Ins (INS) | VAF 161/527 reads (31%) | called by mutect2, pindel, varscan2
- ZNF165 | c.147_150del p.R49Sfs*18 | Frame Shift Del (DEL) | VAF 48/368 reads (13%) | called by pindel, varscan2
- ZNF266 | c.550C>A p.H184N | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.1548_1552delinsT p.H517Ffs*57 | Frame Shift Del (DEL) | VAF 51/369 reads (14%) | called by pindel, varscan2*
- ZNF549 | c.1349G>A p.C450Y (on ENST00000376233 / NM_001199295.2; = p.C437Y on NM_153263.2) | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF565 | c.1382G>A p.C461Y (on ENST00000355114; = p.C421Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 175/372 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF800 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 264/495 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK2 | c.5925C>T p.S1975= | Silent (SNP) | VAF 52/320 reads (16%) | catalogued as rs1443580091; called by muse, mutect2, varscan2
- ART3 | c.378A>G p.R126= | Silent (SNP) | VAF 113/388 reads (29%) | catalogued as COSV100587966; called by muse, mutect2, varscan2
- BCL9 | c.3501A>G p.G1167= | Silent (SNP) | VAF 132/445 reads (30%) | called by muse, mutect2, varscan2
- BMP5 | c.225C>A p.S75= | Silent (SNP) | VAF 58/302 reads (19%) | catalogued as COSV63706774; called by muse, mutect2, varscan2
- CCDC136 | c.3384C>A p.P1128= | Silent (SNP) | VAF 50/524 reads (10%) | called by muse, mutect2
- CDS2 | c.696G>C p.V232= | Silent (SNP) | VAF 54/439 reads (12%) | called by muse, mutect2, varscan2
- CEP120 | c.1887G>A p.P629= | Silent (SNP) | VAF 223/271 reads (82%) | catalogued as rs191422346; called by muse, mutect2, varscan2
- CNNM2 | c.2301G>A p.R767= | Silent (SNP) | VAF 126/411 reads (31%) | called by muse, mutect2, varscan2
- COL6A3 | c.8127G>A p.L2709= | Silent (SNP) | VAF 262/378 reads (69%) | called by muse, mutect2, varscan2
- CPAMD8 | c.45C>T p.P15= | Silent (SNP) | VAF 185/375 reads (49%) | called by muse, mutect2, varscan2
- CTLA4 | c.411G>A p.P137= | Silent (SNP) | VAF 68/282 reads (24%) | catalogued as rs188862082, COSV55592978; ClinVar: likely benign; called by muse, mutect2, varscan2
- DBX1 | c.195G>A p.P65= | Silent (SNP) | VAF 148/777 reads (19%) | catalogued as rs1349282617, COSV99910205; called by muse, mutect2, varscan2
- DLL1 | c.1950C>T p.D650= | Silent (SNP) | VAF 83/488 reads (17%) | catalogued as rs570176152, COSV64536860; called by muse, mutect2, varscan2
- DPP9 | c.2019C>T p.A673= (on ENST00000598800; = p.A702= on NM_139159.5) | Silent (SNP) | VAF 184/378 reads (49%) | catalogued as rs764225972; called by muse, mutect2, varscan2
- ELP1 | c.696A>G p.S232= | Silent (SNP) | VAF 38/309 reads (12%) | called by muse, mutect2, varscan2
- EPC1 | c.867G>A p.Q289= | Silent (SNP) | VAF 14/348 reads (4%) | called by muse, mutect2
- FAM71B | c.780A>T p.G260= | Silent (SNP) | VAF 26/601 reads (4%) | called by muse, mutect2
- FARP1 | c.51G>A p.P17= | Silent (SNP) | VAF 324/477 reads (68%) | catalogued as rs748482677; called by muse, mutect2, varscan2
- FREM2 | c.6786A>G p.E2262= | Silent (SNP) | VAF 44/297 reads (15%) | catalogued as COSV54835207; called by muse, mutect2, varscan2
- GDPD4 | c.60T>C p.T20= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- GFRA4 | c.447G>A p.P149= | Silent (SNP) | VAF 207/1004 reads (21%) | catalogued as rs1265060253; called by muse, mutect2, varscan2
- GRAMD2A | c.784A>C p.R262= | Silent (SNP) | VAF 71/295 reads (24%) | called by muse, mutect2, varscan2
- HS3ST4 | c.333G>A p.P111= | Silent (SNP) | VAF 220/540 reads (41%) | called by muse, mutect2, varscan2
- HSD17B13 | c.159T>G p.T53= | Silent (SNP) | VAF 74/271 reads (27%) | called by muse, mutect2, varscan2
- IL18R1 | c.1170A>G p.G390= | Silent (SNP) | VAF 27/256 reads (11%) | called by muse, mutect2, varscan2
- ITLN1 | c.744C>T p.N248= | Silent (SNP) | VAF 74/360 reads (21%) | catalogued as rs373704009; called by muse, varscan2
- KIAA0408 | c.489C>T p.A163= | Silent (SNP) | VAF 226/236 reads (96%) | called by muse, mutect2, varscan2
- KRT73 | c.402G>A p.E134= | Silent (SNP) | VAF 205/323 reads (63%) | called by muse, mutect2, varscan2
- LIPE | c.1623C>A p.A541= | Silent (SNP) | VAF 65/274 reads (24%) | called by muse, mutect2, varscan2
- LYST | c.10419G>C p.V3473= | Silent (SNP) | VAF 41/320 reads (13%) | called by muse, mutect2, varscan2
- MAN2B2 | c.2538C>T p.P846= | Silent (SNP) | VAF 197/398 reads (49%) | catalogued as rs750939182, COSV99577384; called by muse, mutect2, varscan2
- MAP1S | c.1407A>T p.R469= | Silent (SNP) | VAF 79/440 reads (18%) | catalogued as rs1379540821; called by muse, mutect2, varscan2
- MAST1 | c.1059G>A p.E353= | Silent (SNP) | VAF 75/169 reads (44%) | called by muse, mutect2, varscan2
- MMP16 | c.1008C>T p.P336= | Silent (SNP) | VAF 425/425 reads (100%) | catalogued as rs761488939, COSV54153288, COSV54174570, COSV54183762; called by muse, mutect2, varscan2
- MUC22 | c.4839C>T p.G1613= | Silent (SNP) | VAF 147/873 reads (17%) | catalogued as rs977167089, COSV73736246; called by muse, mutect2, varscan2
- NLRP10 | c.672C>T p.F224= | Silent (SNP) | VAF 197/720 reads (27%) | called by muse, mutect2, varscan2
- NSMCE4A | c.381A>C p.A127= | Silent (SNP) | VAF 128/372 reads (34%) | called by muse, mutect2, varscan2
- PCDHB1 | c.837C>T p.Y279= | Silent (SNP) | VAF 174/535 reads (33%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1779C>T p.D593= | Silent (SNP) | VAF 364/710 reads (51%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.186C>T p.R62= | Silent (SNP) | VAF 98/556 reads (18%) | catalogued as COSV99340524; called by muse, mutect2, varscan2
- PCLO | c.3000A>G p.T1000= | Silent (SNP) | VAF 188/473 reads (40%) | called by muse, mutect2, varscan2
- PROB1 | c.1836G>A p.A612= | Silent (SNP) | VAF 257/767 reads (34%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1692C>T p.F564= | Silent (SNP) | VAF 124/362 reads (34%) | called by muse, mutect2, varscan2
- RTKN | c.1314A>G p.K438= (on ENST00000272430 / NM_001015055.2; = p.K425= on NM_033046.2) | Silent (SNP) | VAF 54/304 reads (18%) | called by muse, mutect2, varscan2
- RUBCN | c.201C>T p.H67= | Silent (SNP) | VAF 314/397 reads (79%) | catalogued as rs367584242; called by muse, mutect2, varscan2
- SCN8A | c.4326C>T p.I1442= | Silent (SNP) | VAF 32/398 reads (8%) | called by muse, mutect2
- SF3B4 | c.1203C>T p.L401= | Silent (SNP) | VAF 257/618 reads (42%) | called by muse, mutect2, varscan2
- SRPK1 | c.1569A>C p.L523= | Silent (SNP) | VAF 37/429 reads (9%) | called by muse, mutect2
- SVOPL | c.60G>A p.G20= | Silent (SNP) | VAF 41/378 reads (11%) | called by muse, mutect2, varscan2
- TBC1D9B | c.433C>A p.R145= | Silent (SNP) | VAF 72/523 reads (14%) | catalogued as COSV62282681; called by muse, mutect2, varscan2
- TMEM132D | c.2301C>A p.V767= | Silent (SNP) | VAF 80/465 reads (17%) | catalogued as COSV67160377; called by muse, mutect2, varscan2
- TWNK | c.1836A>C p.G612= | Silent (SNP) | VAF 96/557 reads (17%) | called by muse, mutect2, varscan2
- UBQLN3 | c.1929C>T p.G643= | Silent (SNP) | VAF 280/432 reads (65%) | catalogued as rs777657726, COSV61163185; called by muse, mutect2
- ZFPM1 | c.978G>C p.L326= | Silent (SNP) | VAF 107/237 reads (45%) | called by muse, mutect2, varscan2
- ZNF782 | c.1350C>T p.F450= | Silent (SNP) | VAF 157/325 reads (48%) | catalogued as rs766203575, COSV56652619; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58839733 G>A | 5'Flank (SNP) | VAF 36/864 reads (4%) | called by muse, mutect2
- CACNB4 | c.148-90322C>A | Intron (SNP) | VAF 215/309 reads (70%) | called by muse, mutect2, varscan2
- CCDC70 | c.-22G>A | 5'UTR (SNP) | VAF 93/289 reads (32%) | catalogued as rs369776694; called by muse, mutect2, varscan2
- DAOA | c.282-64T>C | Intron (SNP) | VAF 37/219 reads (17%) | called by muse, mutect2, varscan2
- DIRC1 | n.519C>A | RNA (SNP) | VAF 39/249 reads (16%) | called by muse, mutect2, varscan2
- FGG | c.*480G>A | 3'UTR (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- GABRD | c.1060-90G>A | Intron (SNP) | VAF 304/775 reads (39%) | catalogued as rs752178524; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4195G>T | Intron (SNP) | VAF 44/500 reads (9%) | called by muse, mutect2
- KCNQ1 | c.1514+36698T>C | Intron (SNP) | VAF 125/441 reads (28%) | called by muse, mutect2, varscan2
- KIAA0895 | c.868-1079G>A | Intron (SNP) | VAF 40/437 reads (9%) | called by muse, mutect2
- NACA | c.70+3569G>C | Intron (SNP) | VAF 109/588 reads (19%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10657G>T | Intron (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
